Surgical pathology report (de-identified scan), TCGA case TCGA-FW-A5DY, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site International Genomics Consortium, specimen TCGA-FW-A5DY-06A (Metastatic).

[page 1 of 2]
Sex: F

Surgical Pathology

ICD03

Melanoma, NOS 8720/3

Site: Lymph Node,
Axilla C77.3

9/11/2013

Histopathological Examination

Pre-Op Diagnosis : Melanoma, Axillary Node Metastasis
Order Physician :
Specimens : Back, melanoma on back, long stitch 12 O'clock, short stitch
3 O'clock
Axilla, right axilla dissection, stitch on apex

Frozen Diagnosis :

Report : GROSS EXAMINATION:

A. The specimen is received in formalin labeled with the name of the patient and labeled as back melanoma.
Tissue: Ellipse with subcutaneous tissue
Size: 3.6 x 3.5 cm
Deep: 1 cm
Lesion: 0.8 cm central scar
Distance from lesion to closest margin: Greater than 1 cm to all margins

Sutures: Long, 12 o'clock; short, 3 o'clock

Inked:

12-3-6 o'clock: Blue

6-9-12 o'clock: Orange

12 o'clock tip: Green

Block summary:

1. 12 and 6 o'clock tips

2-8. Remaining specimen

B. The specimen is received fresh labeled with the name of the patient and labeled as axilla, right axilla dissection, stitch on apex. The specimen consists of a piece of fibrofatty tissue, which measures 11 x 7 x 2.5 cm. A suture marks the apex. The lower portion is dissected for lymph nodes and submitted as follows: Three nodes in block 1 and three nodes in block 2 and one node in each of blocks 3-9. The apical portion is dissected for lymph nodes and submitted as follows: Four nodes in block 10 and one node in each of blocks 11-12.

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

[page 2 of 2]
A. Skin, back, excision:

- Scar, negative for residual melanoma (see comment).
- Multiple step sections examined.

B. Lymph nodes, right axillary, dissection:

- Metastatic melanoma in one of 19 lymph nodes (1/19).
- Metastasis is 1.7 cm in greatest dimension (see comment).

COMMENT:

Each negative node was further evaluated with immunohistochemical stain melanoma cocktail (Melan-A and HMB45), showing no metastatic tumor cells. Controls stained appropriately.

Intradepartmental consultation obtained.

Electronically Signed by:

Requested by	hw 12/21/12	Yes	No
Site/AA Discrepancy			✓
Other Malignancy History			✓
Reviewed Initials	km		12/20/12

Source: NCI Genomic Data Commons file 83042242-1175-4694-a6c8-09d594309eee (TCGA-FW-A5DY.464976CF-0739-43BA-AD4D-788C924F92E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).